Somatic mutation profile of tumor specimen HCM-CSHL-0374-C25-01A (aliquot HCM-CSHL-0374-C25-01A-21D-A79M-36) from HCMI case HCM-CSHL-0374-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Intraductal papillary-mucinous carcinoma, invasive; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 74.7 years (27,272 days).
Specimen HCM-CSHL-0374-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2cbd439-1c41-4168-b7e0-786364366124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0374-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0374-C25-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1009cfec-9bd0-436c-adb4-4105ba6ee8b8

The open-access MAF lists 72 somatic variants for this specimen: 55 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Frame Shift Del 4, Intron 3, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 141/354 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BPIFC | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775661829, COSV55916396; called by muse, mutect2, varscan2
- BRINP1 | c.1562G>T p.R521L | Missense Mutation (SNP) | VAF 45/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56300938; called by muse, mutect2, varscan2
- DHX37 | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs754186165, COSV100439321; called by muse, mutect2, varscan2
- DMRT3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777294931; called by muse, mutect2, varscan2
- DNAH8 | c.5492C>T p.T1831M | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760382625; called by muse, mutect2, varscan2
- DSC2 | c.236T>C p.V79A | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CM166751; called by muse, mutect2, varscan2
- ENPEP | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 74/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs915463280, COSV54453232; called by muse, mutect2, varscan2
- FAM240C | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 35/391 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs1313960522; called by muse, mutect2
- FNDC7 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 103/407 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs572970288, COSV54752204; called by muse, mutect2, varscan2
- GATA1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782632688, COSV64962877; called by muse, mutect2, varscan2
- HIVEP3 | c.4642C>T p.P1548S | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1358942201; called by muse, mutect2, varscan2
- KCNH1 | c.1097G>A p.R366H (on ENST00000271751 / NM_172362.3; = p.R339H on NM_002238.4) | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283810001; called by muse, mutect2, varscan2
- KIAA1958 | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs749207961; called by muse, mutect2, varscan2
- LRRTM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs200699710, COSV69139157, COSV69140155; called by muse, mutect2, varscan2
- NEGR1 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 41/323 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60852524; called by muse, mutect2, varscan2
- NUP210 | c.4527C>G p.S1509R | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV54405068; called by muse, mutect2, varscan2
- PCDHGA6 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 100/681 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.444); catalogued as COSV53933953; called by muse, mutect2, varscan2
- PSG3 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 203/668 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as rs369614691; called by muse, mutect2, varscan2
- RASA3 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 120/501 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.31); catalogued as rs1161979578, COSV61867228; called by muse, mutect2, varscan2
- RBM19 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.59); catalogued as rs373528615; called by muse, mutect2, varscan2
- SATB2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 112/383 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53494135; called by muse, mutect2, varscan2
- SMARCAL1 | c.1594C>T p.L532F | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs968239393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST8SIA4 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 63/226 reads (28%) | PolyPhen benign (0.076); catalogued as rs1394330320, COSV51513558; called by muse, mutect2, varscan2
- SYTL5 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775058607, COSV52900311; called by muse, mutect2, varscan2
- TCF15 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 116/449 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1233735209; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 60/231 reads (26%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TUFM | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as rs769304055; called by muse, mutect2
- UBE2E3 | c.473C>G p.T158S | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1558940397; called by muse, mutect2, varscan2
- ZNF609 | c.2435G>A p.R812H | Missense Mutation (SNP) | VAF 107/412 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182000412; called by muse, mutect2, varscan2
- ADGRV1 | c.6211T>G p.S2071A | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ADH1C | c.157_158insAG p.V53Efs*8 | Frame Shift Ins (INS) | VAF 71/367 reads (19%) | called by mutect2, pindel, varscan2
- ANKZF1 | c.2120_2121del p.S707Ffs*? | Frame Shift Del (DEL) | VAF 38/376 reads (10%) | called by pindel, varscan2
- C5orf51 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- CCDC181 | c.182A>C p.H61P | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CTNND1 | c.1778A>T p.E593V | Missense Mutation (SNP) | VAF 106/401 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLG1 | c.2329A>C p.K777Q (on ENST00000419354 / NM_001290983.1; = p.K799Q on NM_004087.2) | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DMXL2 | c.6649dup p.T2217Nfs*5 | Frame Shift Ins (INS) | VAF 80/379 reads (21%) | called by mutect2, pindel, varscan2
- HCN4 | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNK17 | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 336/618 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- L3MBTL2 | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, varscan2
- MANBA | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NTRK1 | c.649G>T p.V217L | Missense Mutation (SNP) | VAF 80/627 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR5L1 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 88/440 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PCDHGA10 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 84/531 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHYHIPL | c.559T>A p.Y187N | Missense Mutation (SNP) | VAF 65/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHYKPL | c.362T>A p.L121Q | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMARCAD1 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.057); called by muse, varscan2
- TICRR | c.740del p.S247Ffs*18 | Frame Shift Del (DEL) | VAF 95/417 reads (23%) | called by mutect2, pindel, varscan2
- TMEM204 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TTC34 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 65/591 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED8 | c.1272dup p.T425Yfs*7 | Frame Shift Ins (INS) | VAF 20/181 reads (11%) | called by mutect2, pindel, varscan2
- ZFP62 | c.1444T>C p.C482R (on ENST00000502412 / NM_001377944.1; = p.C449R on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF44 | c.1719_1720del p.T575Gfs*6 (on ENST00000356109 / NM_001164276.2; = p.T527Gfs*6 on NM_016264.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/291 reads (15%) | called by mutect2, pindel, varscan2
- ZNF471 | c.158T>A p.L53H | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABR | c.159G>A p.S53= | Silent (SNP) | VAF 176/496 reads (35%) | catalogued as rs147154003; called by muse, mutect2, varscan2
- ADCY5 | c.1776C>T p.A592= | Silent (SNP) | VAF 83/457 reads (18%) | catalogued as rs1331114104; called by muse, mutect2, varscan2
- CHD5 | c.2091C>T p.G697= | Silent (SNP) | VAF 107/384 reads (28%) | catalogued as rs148297777; called by muse, mutect2, varscan2
- EFR3B | c.267C>T p.C89= | Silent (SNP) | VAF 94/366 reads (26%) | called by muse, varscan2
- MEGF8 | c.1173C>T p.G391= | Silent (SNP) | VAF 71/1006 reads (7%) | called by muse, mutect2
- OPLAH | c.1785G>A p.Q595= | Silent (SNP) | VAF 70/523 reads (13%) | called by muse, mutect2, varscan2
- OR2C3 | c.759C>T p.Y253= | Silent (SNP) | VAF 55/348 reads (16%) | catalogued as rs529863004, COSV63574816; called by muse, mutect2, varscan2
- PRR33 | c.600C>T p.A200= | Silent (SNP) | VAF 190/643 reads (30%) | called by muse, mutect2, varscan2
- PTCH1 | c.4086C>T p.P1362= | Silent (SNP) | VAF 119/453 reads (26%) | catalogued as rs375588552; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.4299T>C p.D1433= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as rs1384577551; called by muse, mutect2
- TRPC3 | c.948C>T p.N316= (on ENST00000379645 / NM_001366479.2; = p.N243= on NM_003305.2) | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as COSV53376987; called by muse, mutect2, varscan2
- TYW1 | c.666C>T p.H222= | Silent (SNP) | VAF 53/492 reads (11%) | catalogued as rs1309360283; called by muse, mutect2, varscan2
- ZSWIM1 | c.663C>T p.I221= | Silent (SNP) | VAF 103/383 reads (27%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.30C>T p.P10= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as rs1327383524; called by muse, varscan2
- DNMBP | c.2261-4861G>A | Intron (SNP) | VAF 49/511 reads (10%) | catalogued as rs1235394027; called by muse, mutect2
- KIF1A | c.2555+871C>T | Intron (SNP) | VAF 134/541 reads (25%) | catalogued as rs1553632633; ClinVar: uncertain significance; called by muse, varscan2
- SSX3 | c.466+43G>C | Intron (SNP) | VAF 40/164 reads (24%) | catalogued as rs782376900; called by muse, mutect2, varscan2
